Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5JO, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5JO-01A (Primary Tumor).

[page 1 of 6]
Deliver To:

ICD-6-3

Carcinoma, adrenal cortical 8370/3

Site: ② Adrenal Gland, cortex 874.0

9/20/13

Received

HISTOPATHOLOGY FOR REVIEW

A
T
H
O
L
O
G
Y

Slides were reviewed at the request of _____ (treating surgeon). This review is part of a project examining comparative genomic hybridisation on adrenal tissue frozen at the time of surgery and involves centralised histopathological review including assignment of a Weiss score to a large number of adrenal tumours.

Macroscopic:

The specimen labelled "right adrenal gland" consists of a partly incised adrenal gland, from which a piece of tissue has been removed, weighing 55g and measuring 60mmx40mmx30mm. It is largely replaced by a haemorrhagic tumour measuring 50mmx50mmx30mm. 6 Blocks Sampled.

MICROSCOPIC:

At least 2 Weiss criteria are present (Diffuse architecture, Eosinophilic cytoplasm).

In addition there is probable venous invasion (present in block 1). There is some necrosis (present in block 5) but this appears to be of infarct like necrosis rather than coagulative necrosis. There is some nuclear enlargement and hyperchromasia but I do not think this qualified as nuclear atypia by the Weiss criteria. There is no significant mitotic activity. Atypical mitoses are not present.

I would classify this as an Adrenal Cortical Tumour of uncertain malignant potential. As I am uncertain how to apply the Weiss criteria in this case, I shall send the slides to _____ for his expert opinion.

SUMMARY:

Adrenal Gland: Adrenal cortical tumour of uncertain malignant potential. An additional report clarifying the number of Weiss criteria is pending.

T-93000 M-81400

ADDITIONAL REPORT:

Slides were sent to _____ reports:

for consultation. Dr _____

A
N
A
T
O
M
I
C
A
L

P
A
T
H
O
L
O

COPIES

[page 2 of 6]
Requesting Doctor's Information:

Deliver To

Received

HISTOPATHOLOGY FOR REVIEW

The slides submitted show an unencapsulated adrenocortical neoplasm with a diffuse growth pattern. The cells have predominantly eosinophilic cytoplasm. Broad fibrous bands are present. Nuclear hyperchromasm and pleomorphism is noted (nuclear grade 3 according to Fuhrman's criteria). Vascular invasion is identified on slide 5. No definite necrosis is identified. Rare mitotic figures (2/50HPFs) are seen on the submitted six slides. No atypical mitotic figures are seen. No sinusoidal or capsular invasion is seen.

Utilising the Weiss criteria (American Journal of Surgical Pathology, Volume 8 (3): 163-169, 1984), this neoplasm (1 for vascular invasion, 1 for nuclear grade 3, 1 for diffuse architecture, and 1 for $\leq 25\%$ clear tumour cells). Therefore, this neoplasm would be classified as a malignant neoplasm.

Furthermore, the presence broad fibrous band is used as one feature associated with malignant adrenocortical tumour by Hough's criteria (Hough *et al*, American Journal of Clinical Pathology, 72:390-399, 1979).

As you mentioned, there is a small focus of adrenocortical tissue in the peri-adrenal fat tissue in block 1. We think this is ectopic normal adrenal cortical tissue. A small infarct-like area is identified in block 5 as you mentioned, and we agree with your interpretation. We think that it does not represent coagulative necrosis.

The attending pathologist whose signature appears on this report has reviewed the slides and has edited the gross/or microscopic portion of the report in rendering the final microscopic diagnosis.

DIAGNOSIS:

- Adrenal mass, right adrenalectomy
- Adrenocortical carcinoma, low grade
- Vascular invasion identified
- No capsular invasion or extracapsular extension identified

REPORTING PATHOLOGIST:

(Electronic Signature)

Page 2 of 2

[page 3 of 6]
Patient: _____

Loc: _____

A service operated by

Dob/Age: _____

Doctor: _____

REPORT

Tests requested:
Tests to follow:

CLINICAL NOTES:

Right laparoscopic adrenalectomy

MACROSCOPIC: Dr

Specimen labelled "Right adrenal gland" – Consists of a partly incised adrenal gland, from which a piece of tissue has been removed, weighing 55g and measuring 60mmx40mmx30mm. It is largely replaced by a haemorrhagic tumour measuring 50mmx50mmx30mm.

MICROSCOPIC:

The sections show an adrenal gland. The lesion is composed of cells recapitulating the adrenal cortex. There are areas of haemorrhage and pigment containing cells. There is no significant nuclear pleomorphism, mitotic activity, areas of necrosis or capsular or vascular invasion noted. Cells with clear cytoplasm are also present. The appearances are consistent with an adrenal cortical adenoma.

CONCLUSION:

RIGHT ADRENAL GLAND: Cortical adenoma.

Reported by: _____

electronic signature)

[page 4 of 6]
Adrenal

Patient:

Dob/Age:

Doctor:

Tests requested: HISTO

Tests to follow: <none>

CLINICAL NOTES:

Right laparoscopic adrenalectomy

MACROSCOPIC: Dr

Specimen labelled "Right adrenal gland" - Consists of a partly incised adrenal gland, from which a piece of tissue has been removed, weighing 55g and measuring 60mmx40mmx30mm. It is largely replaced by a haemorrhagic tumour measuring 50mmx50mmx30mm.

MICROSCOPIC:

The sections show an adrenal gland. The lesion is composed of cells recapitulating the adrenal cortex. There are areas of haemorrhage and pigment containing cells. There is no significant nuclear pleomorphism, mitotic activity, areas of necrosis or capsular or vascular invasion noted. Cells with clear cytoplasm are also present. The appearances are consistent with an adrenal cortical adenoma.

CONCLUSION:

RIGHT ADRENAL GLAND: Cortical adenoma.

Reported by: (electronic signature)

FURTHER REPORT:

Slides from this case were reviewed as part of a study utilising comparative hybridization to compare the genotype of benign and malignant adrenal cortical neoplasms. Patient and ethics committee approval etc have been obtained. The study requires centralised pathology review and for all cases to be given a Weiss score. I have reviewed most of the cases, although difficult or borderline cases have been referred to

I thought that this case some atypical features including a diffuse architecture and less than 25% clear cells. I was unsure whether this should be given a point for cytology atypia, vascular space invasion or diffuse architecture. I noted that there was no significant mitotic activity.

3-2-2018

[page 5 of 6]
Dob/Age

Doctor:

REPORT

Tests requested:
Tests to follow:

As it was a borderline case slides were referred to _____ who considers it a low grade adrenocortical carcinoma. A copy of his report is included. I shall return the slides as soon as we receive them back.

Reported by

FURTHER REPORT:

The slides submitted show an unencapsulated adrenocortical neoplasm with a diffuse growth pattern. The cells have predominately eosinophilic cytoplasm. Broad fibrous bands are present. Nuclear hyperchromasm and pleomorphism is noted (nuclear grade III according to Fuhrman's criteria). Vascular invasion is identified on slide 5. No definite necrosis is identified. Rare mitotic figures (2/50HPFs) are seen on the submitted six slides. No atypical mitotic figures are seen. No sinusoidal or capsular invasion is seen.

Utilising the Weiss criteria (American Journal of Surgical Pathology, Volume 8 (3): 163-169, 1984), this neoplasm would rate a score of 4 (1 for vascular invasion, 1 for nuclear grade 3, 1 for diffuse architecture, and 1 for $\leq 25\%$ clear tumour cells). Therefore, this neoplasm would be classified as a malignant neoplasm.

Furthermore, the presence broad fibrous band is used as one feature associated with malignant adrenocortical tumour by Hough's criteria (Hough *et al*, American Journal of Clinical Pathology, 72:390-399, 1979).

Due to the low mitotic rate, this tumour is low grade malignant.

As you mentioned, there is a small focus of adrenocortical tissue in the peri-adrenal fat tissue in block 1. We think this is ectopic normal adrenal cortical tissue. A small infarct-like area is identified in block 5 as you mentioned and we agree with you interpretation. We think that it does not represent coagulative necrosis.

The attending pathologist whose signature appears on this report has reviewed the slides and has edited the gross and/or microscopic portion of the report in rendering the final microscopic diagnosis.

[page 6 of 6]
Dob/Ag

Doctor:

REPORT

Tests requested:
Tests to follow: -

DIAGNOSIS:

ADRENAL MASS, RIGHT ADRENOLECTOMY (

-ADRENOCORTICAL CARCINOMA, LOW GRADE

-VASCULAR INVASION IDENTIFIED

-NO CAPSULAR INVASION OR EXTRACAPSULAR EXTENSION IDENTIFIED

Source: NCI Genomic Data Commons file 2f79f3cd-5367-457f-8255-bb15d46b1602 (TCGA-OR-A5JO.1FECADEA-0B65-451D-933D-2217F9119D35.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).